Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A8OR, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A8OR-01A (Primary Tumor).

[page 1 of 6]
Referring Physician:

DOB: Age: Gender: F

Ref#: Hosp#: Provider Group:

Date of Service: Date Received:

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - F. LEFT BREAST, LEFT AXILLARY TISSUE, PALPABLE NODE, LEFT SENTINEL NODE (), AND SUPERIOR AND INFERIOR SKIN EDGES, SIMPLE MASTECTOMY, EXCISION OF AXILLARY TISSUE, BIOPSY OF PALPABLE NODE, EXCISION OF SUPERIOR AND INFERIOR SKIN EDGES, AND SENTINEL NODE BIOPSY:

- Invasive mucinous carcinoma, Nottingham grade 1.
- Tumor size: 1.7 cm in greatest dimension.
- Tumor location: Subareolar.
- No in situ component identified.
- Margins of resection are negative:
- Invasive carcinoma is at least 3.5 cm from all margins.
- No lymphovascular invasion identified.
- One sentinel and one non-sentinel lymph node, negative for tumor (0/2).
- Focal atypical ductal hyperplasia identified.
- Uninvolved breast parenchyma with fibrocystic changes.
- Benign skin and nipple.
- Palpable node biopsy consists of only adipose tissue.
- Separate left axillary tissue consists of benign fibroadipose tissue.
- Additional superior and inferior skin edges consists of benign skin and subcutaneous tissue.

ICD-O-3
Carcinoma, infiltrating
mucinous 8480/3
Site @ Breast NOS C50.9
9/5/14

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive mucinous carcinoma, Nottingham grade 1.
Primary tumor: pT1c.
Regional lymph nodes: pN0(i-)(sn).
Distant metastasis: N/A.
Stage: IA.
Lymphovascular invasion: Not identified.
Margin status: R0, negative.

Case #:

Printed:

Page 1

This report continues (FINAL)

MR No.

Acct No. -

Patient Name -

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised June 2012).

Previous pathology specimen:

Case #:

Printed:

Page 2

This report continues.. (FINAL)

MR No.
Pathology - Page 2/6

Acct No. -

Patient Name -

- Page 2 Doc# 1

[page 3 of 6]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Simple mastectomy.

Left breast.

Sentinel node biopsy.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor site:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive mucinous carcinoma.

Subareolar.

1.7 cm.

Unifocal.

1 of 3 (Nottingham score 5 of 9).

2 of 3.

2 of 3.

1 of 3.

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Not identified.

Benign skin and nipple.

DUCTAL CARCINOMA IN SITU (DCIS):

Not identified.

MARGINS

Invasive carcinoma:

At least 3.5 cm away from all margins.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit:

Extranodal extension:

2 (one sentinel and one non-sentinel).

0.

N/A.

N/A.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT1c.

pN0(i-)(sn).

N/A.

IA.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

HER2:

Ki-67:

Positive (100%, strong intensity).

Positive (99%, strong intensity).

Negative (score 1+).

7% positive cells.

Case #

Printed:

Page 3

This report continues. (FINAL)

MR No. -

Pathology - Page 3/6

Page 3 Doc# 1

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Signed by:

Source of Specimen:

- A. Sentinel lymph node; Left sentinel node #7
- B. Breast surgical; Left axillary tissue
- C. Breast total mastectomy; Left
- D. Lymph node; Palpable node
- E. Skin; Superior skin edge
- F. Skin; Inferior skin edge

Clinical History/Operative Dx:

Breast cancer.

Intraoperative Diagnosis:

- A. Left sentinel node : Negative for metastasis

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A designated left sentinel node (FS). Initially received in a fresh state for frozen section/touch prep evaluation, is a 3.0 x 2.5 x 1.5 cm portion of yellow-tan fat. Examination reveals a single soft to rubbery pink and tan lymph node measuring 2.5 cm in greatest dimension. A single touch imprint slide is forwarded for microscopic evaluation. The lymph node is entirely submitted for routine histology with a sentinel node protocol performed, on A1 and A2

B. Part B designated left axillary tissue. Received in formalin is a 4 gram portion of yellow-tan fibrofatty soft tissue measuring 3.8 x 2.2 x 1.5 cm. Examination reveals softened yellow-tan fat, without prominent lymph node content. The fatty tissue is entirely submitted for microscopic evaluation for possible minute lymph node content, in B1-B3

C. Received in the fresh state for tumor harvest for tumor bank. The specimen is

Case #:

Page 4

Printed:

This report continues... (FINAL)

[page 5 of 6]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

labeled "left breast mastectomy." Sutures present for orientation purposes. Suture - medial.

Laterality: Left.

Specimen: Simple mastectomy.

Size of mastectomy: (M-L x S-I x A-P): 21.4 x 12.4 x 5.5 cm (including lateral extension of fat).

Axillary tail: 8.0 x 6.8 x 1.8 cm extension of lateral fat.

Skin: 17.7 x 6.4 cm. Nipple/areola: Present.

Specimen weight: 489 grams.

Ink code: Blue - superior-anterior, orange - inferior-anterior, black - deep

Slabs: Total #12, M=1, L=12. Nipple in slabs #6-7.

Time of resection: Not documented.

Time placed into formalin:

Time out of formalin:

Lesion 1: Biopsy site: Spring and hook-shaped radiologic marker appreciated along anterior-lateral periphery of lesion (slab 7).

Size: 1.7 x 1.5 x 1.5 cm, well-circumscribed, pink-tan, gelatinous appearing, mucinous tumor mass.

Location: Subareolar. Involves slabs #6-7.

Distance to nearest margin(s): 3.5 cm from superior superficial and inferior superficial, 1.0 cm from skin, greater than 4.5 cm from most medial and lateral edges of breast.

Non-lesional breast: Serial sections of the breast demonstrate predominantly fatty, glistening, lobular adipose tissue without additional discrete nodularity/lesion. Examination of the most lateral extension of breast reveals a single lymph node, measuring 0.8 x 0.7 x 0.4 cm. Several embedded staples are present.

Cassette summary:

- C1) nipple,
- C2) medial and lateral extension of skin,
- C3) slab 5, medially adjacent to lesion,
- C4) slab 6, tumor,
- C5) slab 6, lesion and skin relationship,
- C6) slab 7, lesion,
- C7) slab 7, tumor, site marked by radiologic marker,
- C8) slab 7, tissue medially inferior to lesion (dense changes),
- C9) slabs 6-7, deep margin,
- C10) slab 7, superior superficial surgical margin adjacent to lesion,
- C11) slab 7, inferior superficial surgical margin adjacent to lesion,
- C12) slab 8, adjacent to lesion,
- C13) slab 10, upper outer quadrant,
- C14) slab 10, lower outer quadrant,
- C15) slab 3, lower inner quadrant,
- C16) slab 3, upper inner quadrant,
- C17) single lymph node.

D. Part D designated palpable node. Received in formalin is a fatty tissue fragment measuring 1.0 x 0.8 x

Case #

Page 5

Printed:

This report continues. (FINAL)

MR No.

Pathology - Page 5/6

Doc# 1

[page 6 of 6]
Patient:

Case:

FINAL SURGICAL PATHOLOGY REPORT

0.3 cm. The tissue is serially sectioned and entirely submitted for microscopic evaluation in D1.

E. Part E is superior skin edge, clip medial. Received in formalin is an elliptical strip of erythematous, pink and tan skin with subcutaneous fat measuring 12.0 x 0.8 cm with a 1.0 cm deep surgical margin. A clip is near one apex designating medial. The superior edge of the skin and surgical margin is now marked blue. Sectioning reveals glistening, yellow-tan subcutaneous fat without grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted for microscopic evaluation in E1.

F. Part F is inferior skin edge, clip medial. Received in formalin is an elliptical strip of erythematous, pink and tan skin with subcutaneous fat measuring 12.5 x 1.0 cm with a 1.8 cm deep surgical margin. A clip is near one apex designating medial. The inferior edge of the skin including superficial surgical margin are now marked green. The specimen is serially sectioned demonstrating glistening, yellow-tan, lobular subcutaneous fat without discrete nodularity or grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted for microscopic evaluation in F1 (two pieces).

Microscopic Description:

A - F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. The sentinel node (part A) was evaluated by H&E levels and OSCAR-cytokeratin immunostains. Controls are appropriate.

Case

Printed:

Page 6

END OF REPORT (FINAL)

MR No. -

Pathology - Page 6/6

Page 3 Doc# 1

Source: NCI Genomic Data Commons file c59da106-7677-4d4e-9cbd-ad3a3f7c84c9 (TCGA-AC-A8OR.1E706FF8-F42C-4FC6-8976-BEB4213BD730.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).